Somatic mutation profile of tumor specimen C3N-00852-03 (aliquot CPT0024670009) from CPTAC case C3N-00852, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.2 years (22,718 days).
Specimen C3N-00852-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 553e8d4c-4bd1-442b-bf75-ee474f7429ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00852-71 (Blood Derived Normal), aliquot CPT0024740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9227d82-b261-402f-a71e-b86ee15d5182

The open-access MAF lists 83 somatic variants for this specimen: 55 protein-altering or splice-affecting, 15 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, Frame Shift Del 8, Intron 7, Nonsense Mutation 3, 5'Flank 3, Splice Site 2, RNA 2, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3M2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51530271; called by muse, mutect2, varscan2
- CEP63 | c.2083A>G p.T695A | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs752659947; called by muse, mutect2
- COBLL1 | c.1256G>A p.R419H (on ENST00000392717; = p.R381H on NM_014900.5) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs149882271, COSV52063648; called by muse, mutect2, varscan2
- COL24A1 | c.2866C>A p.H956N | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs1157875253; called by muse, mutect2, varscan2
- DNAJB2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1252580169; called by muse, mutect2
- HSPA6 | c.1051T>A p.L351M | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.99); catalogued as rs1179945729, COSV100554302, COSV59062758; called by muse, mutect2, varscan2
- INPP5F | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 30/113 reads (27%) | catalogued as COSV100739974; called by muse, mutect2, varscan2
- KIF1B | c.4118G>A p.R1373Q (on ENST00000377086 / NM_001365952.1; = p.R1327Q on NM_015074.3) | Missense Mutation (SNP) | VAF 115/424 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs774615554; called by muse, mutect2, varscan2
- N4BP1 | c.2628G>T p.Q876H | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV52210288; called by muse, mutect2, varscan2
- NDRG1 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs980031699; called by muse, mutect2, varscan2
- NPIPB11 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 51/576 reads (9%) | catalogued as rs1248418769; called by muse, mutect2, varscan2
- OVGP1 | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 174/407 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755771009; called by muse, mutect2, varscan2
- PBRM1 | c.1443+1del p.X481_splice | Splice Site (DEL) | VAF 145/293 reads (49%) | catalogued as COSV56270634; called by mutect2, pindel, varscan2
- TOGARAM1 | c.4821_4824del p.L1607Ffs*12 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs749059577; called by pindel, varscan2
- TTN | c.3121G>A p.E1041K (on ENST00000591111; = p.E995K on NM_003319.4) | Missense Mutation (SNP) | VAF 36/264 reads (14%) | PolyPhen benign (0.013); catalogued as rs201869200, COSV60034296; called by muse, mutect2, varscan2
- VHL | c.469del p.T157Lfs*2 | Frame Shift Del (DEL) | VAF 128/270 reads (47%) | catalogued as COSV56565821; called by mutect2, pindel, varscan2
- AASDH | c.1913del p.F638Sfs*30 | Frame Shift Del (DEL) | VAF 24/135 reads (18%) | called by mutect2, pindel, varscan2
- ACACB | c.6034dup p.Y2012Lfs*6 | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- ALOX12B | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ARHGEF3 | c.1456_1458dup p.M486dup | In Frame Ins (INS) | VAF 84/156 reads (54%) | called by mutect2, pindel, varscan2
- ATP6V0A1 | c.665_674del p.I222Kfs*5 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- ATXN2L | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN5 | c.1811T>A p.V604E (on ENST00000456580; = p.V564E on NM_004055.5) | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.042); called by muse, mutect2
- COL28A1 | c.2515A>C p.I839L | Missense Mutation (SNP) | VAF 114/269 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CSF1R | c.148T>C p.W50R | Missense Mutation (SNP) | VAF 77/428 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP2 | c.1738T>A p.Y580N | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERH | c.232A>C p.T78P | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- FLII | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 45/127 reads (35%) | called by muse, mutect2, varscan2
- FOXP2 | c.1229A>T p.H410L | Missense Mutation (SNP) | VAF 99/392 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FSIP2 | c.13502del p.N4501Ifs*9 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- GJA9 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIVEP3 | c.1903G>T p.G635C | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IGSF11 | c.220A>G p.I74V (on ENST00000393775 / NM_001015887.3; = p.I73V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IL4R | c.1912A>T p.I638F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ISG20L2 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KDM5C | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 141/189 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF7 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLGN2 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NTF3 | c.770del p.T257Nfs*14 | Frame Shift Del (DEL) | VAF 46/226 reads (20%) | called by mutect2, pindel, varscan2
- ODAM | c.56T>G p.I19S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- OR7A5 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLIN2 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPP1R3B | c.476C>G p.T159S | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- R3HDM1 | c.2645T>A p.L882H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RNF157 | c.297-1G>T p.X99_splice | Splice Site (SNP) | VAF 31/108 reads (29%) | called by muse, varscan2
- RUNX2 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SLC13A1 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SSC5D | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D19 | c.1032del p.Y344* | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel*, varscan2*
- TRA2B | c.710_714del p.S237Ifs*23 | Frame Shift Del (DEL) | VAF 72/172 reads (42%) | called by mutect2, pindel, varscan2
- TRPV6 | c.2024A>T p.D675V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, varscan2
- TTN | c.18011T>A p.I6004N (on ENST00000591111; = p.I5077N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- XYLB | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF597 | c.382C>G p.P128A | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZSWIM4 | c.932T>A p.L311Q | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); called by muse, mutect2
- CDC16 | c.1525A>C p.R509= | Silent (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.1188G>A p.P396= (on ENST00000450689 / NM_001142749.3; = p.P229= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs751388859; called by muse, mutect2, varscan2
- GPATCH1 | c.36G>C p.L12= | Silent (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2
- GPR162 | c.630C>A p.P210= | Silent (SNP) | VAF 52/126 reads (41%) | called by muse, mutect2, varscan2
- GRIN3A | c.1323T>A p.T441= | Silent (SNP) | VAF 10/289 reads (3%) | called by muse, mutect2
- LRRC56 | c.786T>C p.L262= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- MAGI3 | c.3070C>T p.L1024= | Silent (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2, varscan2
- MYPN | c.714G>A p.A238= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs757661676; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHF23 | c.930A>G p.Q310= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- PLK1 | c.978G>T p.S326= | Silent (SNP) | VAF 50/397 reads (13%) | called by muse, mutect2, varscan2
- R3HDM2 | c.1257C>A p.P419= | Silent (SNP) | VAF 44/106 reads (42%) | called by muse, varscan2
- SGCB | c.870T>C p.C290= | Silent (SNP) | VAF 88/200 reads (44%) | called by muse, mutect2, varscan2
- TAOK1 | c.414A>G p.G138= | Silent (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- TTC21B | c.2805T>C p.D935= | Silent (SNP) | VAF 114/442 reads (26%) | called by muse, mutect2, varscan2
- ZNF217 | c.792C>T p.D264= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as rs563819509; called by muse, mutect2, varscan2
- CZIB | c.6+100G>T | Intron (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.506C>G | RNA (SNP) | VAF 53/128 reads (41%) | called by muse, mutect2, varscan2
- DZANK1 | c.543+749G>T | Intron (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630404 C>A | 5'Flank (SNP) | VAF 79/215 reads (37%) | catalogued as rs1272227389; called by muse, mutect2, varscan2
- FLT4 | c.3332-22del | Intron (DEL) | VAF 18/62 reads (29%) | catalogued as COSV99988381; called by mutect2, pindel, varscan2
- GGT7 | c.1726-126G>A | Intron (SNP) | VAF 35/109 reads (32%) | catalogued as rs760483256; called by muse, mutect2, varscan2
- HLA-L | n.992G>C | RNA (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- INPP5B | c.772+13G>A | Intron (SNP) | VAF 69/143 reads (48%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701797 ins C | 3'Flank (INS) | VAF 53/195 reads (27%) | called by mutect2, pindel, varscan2
- RPS6KA1 | c.109-928G>C | Intron (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- SRRM2 | c.690-44T>A | Intron (SNP) | VAF 30/113 reads (27%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439083 C>T | 5'Flank (SNP) | VAF 61/112 reads (54%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439084 T>A | 5'Flank (SNP) | VAF 62/112 reads (55%) | called by muse, mutect2, varscan2
